Gene-level copy-number profile of tumor specimen TARGET-40-PARFTG-01A from TARGET case TARGET-40-PARFTG, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.7 years (4,987 days).
Specimen TARGET-40-PARFTG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.52ff6ae2-3d4b-5575-b2bc-9762ded1a324.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PARFTG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 396 have no estimate.
https://portal.gdc.cancer.gov/files/245dbcea-1c24-41b9-a340-44c4acc58e5d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 615; copy number 1: 868; copy number 2: 25,841; copy number 3: 9,923; copy number 4: 20,791; copy number 5: 780; copy number 6: 914; copy number 7: 236; copy number 8: 44; copy number 9: 17; copy number 11: 74; copy number 14: 1; copy number 15: 28; copy number 16: 7; copy number 19: 10; copy number 21: 50; copy number 22: 8; copy number 28: 20.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:52,570,648–52,572,522, 1 gene: CRTC1P1.
- chr3:99,215,224–100,181,732, 10 genes (within-gene range 0–2): ACTG1P13, AC107297.1, AC078828.1, AC107029.1, AC107029.2, COL8A1, AC069222.1, CMSS1, FILIP1L, MIR3921.
- chr4:68,447,463–68,712,498, 8 genes: TMPRSS11E, UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1.
- chr4:138,425,523–138,436,869, 1 gene (within-gene range 0–1): LINC00500.
- chr6:121,079,494–121,354,460, 2 genes (within-gene range 0–1): TBC1D32, RNU6-1286P.
- chr9:17,096,301–17,503,923, 3 genes (within-gene range 0–2): RPS29P33, AL162725.1, CNTLN.
- chr9:20,331,446–20,622,499, 6 genes (within-gene range 0–2): AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1.
- chr9:20,999,509–22,455,740, 56 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr9:73,474,378–73,476,073, 1 gene: DPP3P2.
- chr10:131,092,391–131,311,721, 1 gene (within-gene range 0–2): TCERG1L.
- chr20:7,831,798–8,043,512, 5 genes: AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1.
- chr20:8,097,824–8,099,774, 1 gene: PHKBP1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,139 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,155,579–39,034,636, 83 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:67,832,303–73,915,340, 70 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:186,176,814–190,478,404, 41 genes, copy number 5–7 (within-gene range 2–7): AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1.
- chr3:107,834,586–107,928,907, 2 genes, copy number 5: LINC00636, LINC00635.
- chr3:108,296,490–117,139,389, 134 genes, copy number 5–28 (within-gene range 2–28) (broad region; genes not listed).
- chr3:124,374,332–125,063,710, 15 genes, copy number 5: MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137, AC117488.1.
- chr4:30,718,805–31,558,831, 7 genes, copy number 5: AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501.
- chr4:54,221,126–58,118,070, 83 genes, copy number 5 (broad region; genes not listed).
- chr4:114,827,763–115,143,303, 2 genes, copy number 5 (within-gene range 3–5): NDST4, MRPS33P3.
- chr6:32,459,821–32,589,848, 5 genes, copy number 7 (within-gene range 2–7): HLA-DRB9, HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr8:109,573,978–109,691,791, 2 genes, copy number 6: SYBU, AC079061.1.
- chr8:113,950,886–120,813,359, 62 genes, copy number 6–11 (broad region; genes not listed).
- chr8:121,612,116–145,066,685, 446 genes, copy number 5–6 (broad region; genes not listed).
- chr9:14,475–2,643,359, 38 genes, copy number 5 (within-gene range 4–5): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1.
- chr9:14,395,791–17,114,122, 36 genes, copy number 5–7 (within-gene range 0–7): AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1.
- chr9:22,646,200–24,088,051, 15 genes, copy number 5: LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr10:108,848,186–109,239,746, 4 genes, copy number 6: MAPKAPK5P1, RN7SKP278, RNU5B-6P, RNU6-839P.
- chr10:110,869,743–110,919,201, 7 genes, copy number 6: AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1.
- chr12:18,242,961–23,251,499, 74 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–19,957,996, 83 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:28,264,390–29,372,406, 18 genes, copy number 5 (within-gene range 3–5): BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P.
- chr14:43,274,824–43,596,683, 6 genes, copy number 5: TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P.
- chr14:105,764,503–106,318,236, 92 genes, copy number 7 (broad region; genes not listed).
- chr15:56,542,952–56,629,592, 1 gene, copy number 5 (within-gene range 2–5): AC090518.1.
- chr15:56,634,038–56,634,167, 1 gene, copy number 5: Y_RNA.
- chr15:57,405,074–57,405,175, 1 gene, copy number 5: RNU6-844P.
- chr15:59,768,352–59,873,495, 3 genes, copy number 9: RPS3AP6, AC092079.2, AC092079.1.
- chr15:61,852,389–62,060,473, 1 gene, copy number 8 (within-gene range 2–8): VPS13C.
- chr15:62,060,503–62,165,285, 4 genes, copy number 8: AC104590.1, C2CD4A, NPM1P47, C2CD4B.
- chr15:89,087,078–90,856,207, 83 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr15:94,231,538–94,726,519, 7 genes, copy number 5: MCTP2, AC135626.1, AC135626.2, AC009432.2, LINC02852, AC009432.1, AC022308.1.
- chr15:94,855,586–94,857,011, 1 gene, copy number 14: AC107976.1.
- chr15:95,280,753–98,320,237, 56 genes, copy number 7: AC104260.2, AC104260.3, LINC00924, AC027013.1, AC015574.1, RNU2-3P, AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1, FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6, AC022523.1, RNU6-1186P, LINC01582, AC022523.3, AC022523.2, AC015722.1, AC015722.2.
- chr15:98,646,951–99,733,561, 28 genes, copy number 6: IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4.
- chr15:100,074,081–100,129,743, 2 genes, copy number 6: RNA5SP402, AC022710.1.
- chr16:46,469,341–46,973,674, 19 genes, copy number 5 (within-gene range 2–5): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2, DNAJA2.
- chr17:69,414,697–83,095,122, 478 genes, copy number 6–7 (broad region; genes not listed).
- chr19:57,389,850–57,644,041, 22 genes, copy number 5: ZNF548, AC003002.3, AC003002.2, ZNF17, ZNF749, AC004076.1, AC004076.2, VN1R1, VN1R107P, ZNF772, AC003005.2, ZNF419, AC003005.1, ZNF773, ZNF549, ZNF550, ZNF416, ZIK1, ZNF530, ZNF134, AC003682.1, ZNF211.
- chr21:45,478,266–46,665,124, 40 genes, copy number 5–8: MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.
- chr22:44,566,965–46,762,563, 60 genes, copy number 6–7: KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1, AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A, FAM118A, SMC1B, RIBC2, AL021391.1, FBLN1, LINC01589, RNU6-1161P, Z95331.1, ATXN10, MIR4762, Z84478.1, BX324167.2, BX324167.1, WNT7B, BX537318.2, BX537318.1, LINC00899, PRR34, AL121672.3, PRR34-AS1, MIRLET7BHG, AL121672.1, AL121672.2, MIR3619, MIRLET7A3, MIR4763, MIRLET7B, PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1.

Autosomal genes at a single copy (total copy number 1): 868. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
